Somatic mutation profile of tumor specimen MP2PRT-PATGUY-TMP1-A (aliquot MP2PRT-PATGUY-TMP1-A-1-0-D-A817-36) from MP2PRT case MP2PRT-PATGUY, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.8 years (668 days).
Specimen MP2PRT-PATGUY-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9e50f3f8-40ab-40a0-8c0b-e38cff5c17cd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATGUY-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATGUY-NB1-A-1-0-D-A817-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/077a8e21-ef84-4a5f-b8ea-5faef6e100a9

The open-access MAF lists 16 somatic variants for this specimen: 13 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 10, Silent 3, Frame Shift Ins 1, In Frame Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 161/345 reads (47%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TGFB2 | c.821dup p.N274Kfs*19 | Frame Shift Ins (INS) | VAF 176/379 reads (46%) | catalogued as rs863223796; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- DOCK3 | c.4363C>T p.R1455W | Missense Mutation (SNP) | VAF 32/335 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs1222556951; called by muse, mutect2
- DYNC1I1 | c.1120C>T p.R374* | Nonsense Mutation (SNP) | VAF 204/433 reads (47%) | catalogued as rs776347302, COSV61460821; called by muse, mutect2, varscan2
- GOLGA6L6 | c.1211C>T p.A404V | Missense Mutation (SNP) | VAF 64/773 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs749982824, COSV71181435; called by muse, varscan2
- GRIP2 | c.736G>A p.V246I (on ENST00000619221; = p.V149I on NM_001080423.4) | Missense Mutation (SNP) | VAF 116/270 reads (43%) | SIFT tolerated (0.39); PolyPhen benign (0.026); catalogued as rs1225980454, COSV56122570; called by muse, mutect2, varscan2
- KCNMA1 | c.3704G>A p.R1235Q (on ENST00000286628 / NM_001161352.2; = p.R1177Q on NM_002247.4) | Missense Mutation (SNP) | VAF 81/198 reads (41%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.222); catalogued as rs75843969; ClinVar: likely benign; called by muse, mutect2, varscan2
- PIK3R1 | c.1735_1740del p.Q579_Y580del (on ENST00000521381 / NM_181523.3; = p.Q309_Y310del on NM_181504.4) | In Frame Del (DEL) | VAF 54/266 reads (20%) | catalogued as rs751582616; called by mutect2, pindel, varscan2
- ZHX2 | c.274G>A p.E92K | Missense Mutation (SNP) | VAF 223/457 reads (49%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.646); catalogued as rs771818495, COSV58714220; called by muse, mutect2, varscan2
- ZNF723 | c.718G>A p.V240M | Missense Mutation (SNP) | VAF 37/253 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.205); catalogued as rs12978254, COSV74102978; called by muse, mutect2, varscan2
- CD80 | c.39G>T p.K13N | Missense Mutation (SNP) | VAF 137/322 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- GABRB3 | c.685G>A p.A229T | Missense Mutation (SNP) | VAF 9/216 reads (4%) | SIFT tolerated (0.2); PolyPhen benign (0.015); called by muse, mutect2
- WHAMM | c.1409C>T p.S470F | Missense Mutation (SNP) | VAF 55/274 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ARMC12 | c.996T>C p.S332= (on ENST00000373866 / NM_001286574.2; = p.S359= on NM_145028.5) | Silent (SNP) | VAF 54/240 reads (23%) | called by muse, mutect2, varscan2
- NR2F2 | c.255G>A p.K85= | Silent (SNP) | VAF 18/572 reads (3%) | called by muse, mutect2
- ST14 | c.456C>T p.I152= | Silent (SNP) | VAF 95/391 reads (24%) | catalogued as rs748885098; called by muse, mutect2, varscan2
